Somatic mutation profile of tumor specimen TARGET-20-PARNTM-09A (aliquot TARGET-20-PARNTM-09A-01D) from TARGET case TARGET-20-PARNTM, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,325 days).
Specimen TARGET-20-PARNTM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cb43684-883b-49bc-b748-19ef0606620f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARNTM-14A (Bone Marrow Normal), aliquot TARGET-20-PARNTM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34745a9f-5e5b-40b2-b1e7-fba06232af5f

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.182A>T p.D61V | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs121918461, CM013415, CM098208, COSV61004983, COSV61005256, COSV61011211; ClinVar: pathogenic; called by muse, mutect2
- KRAS | c.171_172insCTCGGC p.D57_T58insLG | In Frame Ins (INS) | VAF 12/109 reads (11%) | catalogued as COSV55966690; called by mutect2, pindel
- LLGL1 | c.1193C>T p.S398L | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as rs370740868; called by muse, mutect2, varscan2
- AHNAK2 | c.2107C>G p.P703A | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2
